Somatic mutation profile of tumor specimen TCGA-BR-4256-01A (aliquot TCGA-BR-4256-01A-01D-1126-08) from TCGA case TCGA-BR-4256, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; Tumor grade: G2; Age at diagnosis: 80.6 years (29,441 days).
Specimen TCGA-BR-4256-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47847b0d-36c3-4691-9a71-4643acd4d4a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4256-11A (Solid Tissue Normal), aliquot TCGA-BR-4256-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe1cde8d-4864-413b-be47-58eb97d1e18e

The open-access MAF lists 1,160 somatic variants for this specimen: 883 protein-altering or splice-affecting, 258 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 579, Silent 258, Frame Shift Del 198, Frame Shift Ins 37, Nonsense Mutation 35, Splice Site 15, In Frame Del 10, Intron 8, Splice Region 7, 5'UTR 4, 3'Flank 3, 3'UTR 2.

Variants (750 of 1,160; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GCK | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs1375656631, CM980894, COSV60787622; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLDC | c.887T>G p.L296R | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs386833591, CM061035, COSV58683381; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.491del p.K164Rfs*3 | Frame Shift Del (DEL) | VAF 13/113 reads (12%) | catalogued as rs786204900, COSV64297274; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SERPINA1 | c.1158del p.E387Rfs*11 | Frame Shift Del (DEL) | VAF 13/94 reads (14%) | catalogued as rs764325655, CD890162; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SIX3 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as rs1558420022, CD064630, COSV53228210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC26A2 | c.438del p.F146Lfs*26 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | catalogued as rs769859976; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TJP2 | c.2438del p.F813Sfs*12 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as rs776869985; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- VPS13B | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as rs180177354, CM041269, COSV62023690; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 13/102 reads (13%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADAT | c.257G>T p.W86L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV61787790; called by muse, mutect2, varscan2
- ABCA12 | c.5993C>T p.S1998F (on ENST00000272895 / NM_173076.3; = p.S1680F on NM_015657.3) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55969798; called by muse, mutect2, varscan2
- ABCB5 | c.3576+2T>C p.X1192_splice (on ENST00000404938 / NM_001163941.2; = p.X747_splice on NM_178559.6) | Splice Site (SNP) | VAF 16/93 reads (17%) | catalogued as COSV51716734; called by muse, mutect2, varscan2
- AC126283.2 | c.917T>A p.I306N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.466); catalogued as CM126994, COSV67099460; called by muse, mutect2, varscan2
- ACACB | c.654-1G>T p.X218_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | catalogued as COSV58142088; called by muse, mutect2, varscan2
- ACAD10 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 24/171 reads (14%) | catalogued as rs377612660; called by muse, mutect2, varscan2
- ACAD9 | c.890T>C p.M297T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1219386038, COSV58309196; called by muse, mutect2, varscan2
- ACBD3 | c.425G>T p.R142M | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64730912; called by muse, mutect2, varscan2
- ACIN1 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs768644124; called by mutect2, varscan2
- ACSM2B | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as COSV100313001; called by muse, mutect2, varscan2
- ACTBL2 | c.521A>G p.H174R | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as rs771324969, COSV70661570; called by muse, mutect2, varscan2
- ADA | c.1052A>G p.Y351C | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63069104; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV63203172; called by muse, mutect2, varscan2
- ADCY10 | c.4790dup p.N1597Kfs*8 | Frame Shift Ins (INS) | VAF 18/118 reads (15%) | catalogued as rs753500756; called by mutect2, varscan2
- ADHFE1 | c.755C>A p.T252N | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52557960; called by muse, mutect2, varscan2
- ADIPOQ | c.502A>G p.M168V | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV57859733; called by muse, mutect2, varscan2
- AEBP1 | c.2918T>C p.I973T | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV56259970; called by muse, mutect2, varscan2
- AGPAT4 | c.907del p.R303Gfs*7 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs750826126, COSV57248889; called by pindel, varscan2
- AHNAK | c.4585G>T p.E1529* | Nonsense Mutation (SNP) | VAF 45/288 reads (16%) | catalogued as COSV57224363; called by muse, mutect2, varscan2
- AHNAK2 | c.9052C>T p.Q3018* | Nonsense Mutation (SNP) | VAF 43/303 reads (14%) | catalogued as rs1279438032, COSV60924552; called by muse, mutect2, varscan2
- ALDH1A1 | c.312G>T p.A104= | Splice Region (SNP) | VAF 14/113 reads (12%) | catalogued as COSV52793263; called by muse, mutect2, varscan2
- ALDOB | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1162480440, COSV66398181, COSV66398392; called by muse, mutect2, varscan2
- ALG1 | c.1088G>C p.G363A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM166632; called by muse, mutect2
- ALG12 | c.836T>C p.I279T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | PolyPhen possibly damaging (0.446); catalogued as COSV58208042; called by muse, mutect2, varscan2
- ALKBH3 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as rs200996094; called by muse, mutect2, varscan2
- ALOX5 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV65553675; called by muse, mutect2, varscan2
- ALPK2 | c.3556C>T p.R1186C | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as rs139032503; called by mutect2, varscan2
- ANK3 | c.11122G>T p.A3708S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.006); catalogued as COSV99781449; called by muse, mutect2
- ANKRD28 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67519561; called by muse, mutect2, varscan2
- ANKRD45 | c.623dup p.N208Kfs*2 | Frame Shift Ins (INS) | VAF 7/56 reads (13%) | catalogued as rs1256946605; called by pindel, varscan2
- AOC1 | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as rs764404660, COSV62870162; called by muse, mutect2, varscan2
- AP1G2 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV55339303; called by muse, mutect2, varscan2
- APBB2 | c.1774G>A p.V592M (on ENST00000295974 / NM_001166050.2; = p.V593M on NM_004307.2) | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199509946, COSV55963812; called by muse, mutect2, varscan2
- APBB2 | c.1527-1G>T p.X509_splice (on ENST00000295974 / NM_001166050.2; = p.X510_splice on NM_004307.2) | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV55959031; called by muse, mutect2, varscan2
- APLP2 | c.678G>T p.E226D | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs142841183, COSV53839157; called by muse, mutect2, varscan2
- AQR | c.3620T>C p.V1207A | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV50044431; called by muse, mutect2, varscan2
- AQR | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV50044518; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 18/146 reads (12%) | catalogued as rs773922861; called by mutect2, pindel
- ARHGAP30 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.459); catalogued as rs1016750809, COSV63518289, COSV63518570; called by muse, mutect2, varscan2
- ARHGAP5 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100565599; called by muse, mutect2
- ARHGAP5 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.269); catalogued as COSV61538319; called by muse, mutect2, varscan2
- ARHGEF10L | c.2815G>A p.A939T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs370788733, COSV51437899; called by muse, mutect2, varscan2
- ARHGEF5 | c.4094C>T p.T1365I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV50215286; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as COSV61372705; called by pindel, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID1B | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.742); catalogued as rs563771544, COSV51673928; called by muse, mutect2, varscan2
- ARMC9 | c.1716C>T p.S572= | Splice Region (SNP) | VAF 22/169 reads (13%) | catalogued as rs758177199, COSV63020011; called by muse, mutect2, varscan2
- ARSB | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs756933794, COSV53727411; called by muse, mutect2, varscan2
- ASCC3 | c.4409T>C p.V1470A | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64978623; called by muse, mutect2, varscan2
- ASGR1 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.115); catalogued as rs1162770344, COSV52649409; called by muse, mutect2, varscan2
- ASXL3 | c.1614A>C p.E538D | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV52474558; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 34/129 reads (26%) | catalogued as rs746676748; called by mutect2, varscan2
- ATCAY | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as rs773910189, COSV56658047; called by muse, mutect2, varscan2
- ATF7IP | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV53771189, COSV53775170; called by muse, mutect2, varscan2
- ATP13A4 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61323843; called by muse, mutect2, varscan2
- ATP2A2 | c.2462G>A p.R821Q | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778998667, COSV57875652; called by muse, mutect2, varscan2
- ATP6V1H | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs775204858, COSV62219009; called by mutect2, varscan2
- ATXN1 | c.2311A>G p.K771E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55225983; called by muse, mutect2, varscan2
- BBS10 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV67913351; called by muse, mutect2, varscan2
- BBS9 | c.1375G>A p.V459I | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54155725, COSV99629413; called by muse, mutect2, varscan2
- BMS1 | c.2313G>T p.K771N | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as COSV65734936; called by muse, mutect2, varscan2
- BOD1L1 | c.3879G>T p.R1293S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV50037393; called by muse, mutect2, varscan2
- BRF1 | c.1907A>G p.Y636C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV59272012; called by muse, mutect2, varscan2
- BRMS1 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 27/266 reads (10%) | catalogued as rs778576158, COSV60820495; called by muse, mutect2
- BRPF3 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs369260945; called by muse, mutect2, varscan2
- BTBD2 | c.1448T>C p.L483P | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1459651722, COSV99724888; called by muse, mutect2
- C10orf90 | c.185A>C p.K62T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.544); catalogued as rs540844124, COSV52960760; called by mutect2, varscan2
- C11orf45 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as COSV57969262; called by muse, mutect2, varscan2
- C18orf54 | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV55617389, COSV55618867; called by muse, mutect2, varscan2
- C1QTNF6 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1464926135, COSV55397128; called by muse, mutect2
- C1RL | c.1393G>T p.G465W | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56926183; called by muse, mutect2, varscan2
- C1orf56 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV54848245; called by muse, mutect2
- C1orf56 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1349400228, COSV54848246; called by muse, mutect2, varscan2
- C2orf16 | c.5672T>C p.M1891T | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs766219115, COSV62677409; called by muse, mutect2, varscan2
- C8A | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV63485808; called by muse, mutect2, varscan2
- CACNA1I | c.854del p.P285Rfs*69 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as COSV100359312; called by mutect2, pindel, varscan2
- CADM1 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.688); catalogued as COSV59018671; called by muse, mutect2, varscan2
- CALCOCO1 | c.702G>T p.E234D | Missense Mutation (SNP) | VAF 52/420 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV50418793; called by muse, mutect2, varscan2
- CAMSAP1 | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV56725119, COSV56726219; called by muse, mutect2, varscan2
- CANX | c.1305del p.F435Lfs*12 | Frame Shift Del (DEL) | VAF 16/106 reads (15%) | catalogued as rs760711956; called by mutect2, varscan2
- CATSPER1 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs370786090; called by muse, mutect2, varscan2
- CCDC171 | c.2075del p.N692Tfs*5 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs1463058740; called by mutect2, pindel
- CCDC174 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs370988051; called by mutect2, varscan2
- CCDC191 | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55674904; called by muse, mutect2, varscan2
- CCDC40 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs769458274, COSV53902743; called by muse, mutect2, varscan2
- CCDC88C | c.3050G>A p.G1017E | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66240288; called by muse, mutect2, varscan2
- CCDC93 | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60123132; called by muse, mutect2, varscan2
- CCNL2 | c.863del p.K288Rfs*65 | Frame Shift Del (DEL) | VAF 23/130 reads (18%) | catalogued as COSV68766101, COSV68766120; called by mutect2, pindel, varscan2
- CCPG1 | c.1412G>A p.G471D | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.036); catalogued as COSV51243340; called by muse, mutect2, varscan2
- CCR3 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100656674; called by muse, mutect2, varscan2
- CD1B | c.62-2A>G p.X21_splice | Splice Site (SNP) | VAF 30/247 reads (12%) | catalogued as COSV63804881; called by muse, varscan2
- CDC42BPG | c.3992T>C p.V1331A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61348536; called by muse, mutect2, varscan2
- CDH10 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs1261442492, COSV100049919, COSV52591381; called by muse, mutect2, varscan2
- CDH2 | c.2690T>A p.L897H | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52270931, COSV52290993; called by muse, mutect2, varscan2
- CDH4 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV64668453; called by mutect2, varscan2
- CDHR3 | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV58420136; called by muse, mutect2, varscan2
- CDK13 | c.3671C>A p.P1224H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV51704270; called by mutect2, varscan2
- CDK5RAP2 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as COSV62576855; called by muse, mutect2, varscan2
- CEMIP | c.540del p.F180Lfs*44 | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | catalogued as rs753314096; called by mutect2, pindel, varscan2
- CEP128 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.085); catalogued as COSV55385812, COSV55395107; called by muse, mutect2, varscan2
- CEP63 | c.1926G>A p.M642I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV59678306; called by muse, mutect2, varscan2
- CFAP44 | c.2305T>C p.Y769H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV55614449; called by muse, mutect2
- CFH | c.3607C>T p.R1203W | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.244); catalogued as rs145347741, CM100538; called by muse, mutect2, varscan2
- CGNL1 | c.1243A>C p.S415R | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV99848836; called by muse, mutect2, varscan2
- CHAF1B | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023286; called by muse, mutect2, varscan2
- CHD7 | c.3679A>G p.T1227A | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV71113307; called by muse, mutect2, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 26/172 reads (15%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHMP3 | c.285C>A p.L95= | Splice Region (SNP) | VAF 10/79 reads (13%) | catalogued as COSV55687279; called by mutect2, varscan2
- CHRDL1 | c.952G>A p.G318S (on ENST00000372045; = p.G324S on NM_145234.4) | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV54327461; called by muse, varscan2
- CHRDL1 | c.116G>A p.R39K (on ENST00000372045; = p.R45K on NM_145234.4) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.245); catalogued as COSV54327472; called by muse, mutect2, varscan2
- CHRNB4 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404927086, COSV55716849; called by muse, mutect2, varscan2
- CHST5 | c.980A>C p.N327T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV60340948; called by muse, mutect2, varscan2
- CKMT2 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1042613615, COSV54172768; called by muse, mutect2, varscan2
- CLIC1 | c.188A>G p.Q63R | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.466); catalogued as COSV65384281; called by muse, mutect2, varscan2
- CMTM1 | c.180del p.F60Lfs*3 (on ENST00000457188 / NM_181269.3; = p.F177Lfs*3 on NM_052999.4) | Frame Shift Del (DEL) | VAF 20/136 reads (15%) | catalogued as rs773521289; called by mutect2, varscan2
- CNTNAP1 | c.3676C>T p.R1226* | Nonsense Mutation (SNP) | VAF 27/130 reads (21%) | catalogued as rs775153843, COSV52848830; called by muse, mutect2, varscan2
- COL11A2 | c.3049C>A p.P1017T (on ENST00000341947 / NM_080680.3; = p.P910T on NM_080679.2) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.473); catalogued as COSV100554368; called by mutect2, varscan2
- COL5A3 | c.5091+2T>C p.X1697_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | catalogued as COSV53416396; called by muse, mutect2, varscan2
- COL6A3 | c.6629G>A p.G2210D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55101704; called by muse, mutect2, varscan2
- CORO1B | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV58171408; called by muse, mutect2, varscan2
- CPA5 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62569371, COSV62570409; called by muse, mutect2, varscan2
- CPEB2 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1306439077, COSV52594208; called by muse, mutect2, varscan2
- CPSF1 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62941753, COSV62942868; called by muse, mutect2, varscan2
- CPT1B | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV56418203; called by muse, mutect2, varscan2
- CRB2 | c.1519C>A p.L507M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63504714; called by muse, mutect2, varscan2
- CSAD | c.361G>A p.A121T (on ENST00000444623 / NM_001244705.2; = p.A148T on NM_015989.5) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138203066, COSV57244266; called by mutect2, varscan2
- CSF2RA | c.38T>C p.L13S | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as COSV62626030; called by muse, mutect2, varscan2
- CSGALNACT2 | c.940G>T p.G314* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as COSV65676185; called by muse, mutect2, varscan2
- CSH1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs139446025; called by mutect2, varscan2
- CSMD1 | c.8876G>A p.R2959H (on ENST00000520002; = p.R2958H on NM_033225.6) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV59313602; called by muse, mutect2
- CSMD3 | c.9922A>G p.I3308V (on ENST00000297405 / NM_001363185.1; = p.I3139V on NM_052900.3) | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); catalogued as COSV52267456; called by muse, mutect2, varscan2
- CTAGE1 | c.2069del p.P690Hfs*30 | Frame Shift Del (DEL) | VAF 19/146 reads (13%) | catalogued as rs766584848; called by mutect2, pindel, varscan2
- CTNND2 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs747652289, COSV58912091; called by mutect2, varscan2
- CTTNBP2 | c.2716A>G p.I906V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as COSV50442673; called by muse, mutect2, varscan2
- CYP19A1 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1451235851, CM151266, COSV53061373; called by muse, mutect2, varscan2
- CYP20A1 | c.903del p.K301Nfs*6 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | catalogued as rs778884333; called by mutect2, varscan2
- CYP2J2 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64606795; called by muse, mutect2, varscan2
- CYP7A1 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV56964822; called by mutect2, varscan2
- DAOA | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV61603234; called by muse, mutect2, varscan2
- DCC | c.2299C>A p.P767T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59123411; called by muse, mutect2, varscan2
- DCLK2 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV56209327; called by muse, mutect2, varscan2
- DDB2 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as COSV57040057; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 16/106 reads (15%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX41 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57905072; called by muse, mutect2, varscan2
- DDX43 | c.1092del p.G365Vfs*2 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | catalogued as rs1424884917, COSV64836411; called by mutect2, pindel, varscan2
- DHDH | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 16/123 reads (13%) | catalogued as COSV55482908; called by muse, mutect2, varscan2
- DHX36 | c.1796_1797del p.R599Kfs*17 | Frame Shift Del (DEL) | VAF 22/208 reads (11%) | catalogued as rs778305476; called by pindel, varscan2
- DHX8 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs879524424, COSV52255463, COSV99292304; called by muse, mutect2, varscan2
- DLX3 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315166585, COSV71547853; called by muse, mutect2, varscan2
- DMBT1 | c.1730G>A p.G577D | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV57545648; called by muse, mutect2, varscan2
- DNAH10 | c.548T>G p.I183S (on ENST00000409039; = p.I122S on NM_207437.3) | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV68998711; called by muse, mutect2, varscan2
- DNAH17 | c.7754G>A p.R2585H | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778812435, COSV67749196; called by mutect2, varscan2
- DNAJB4 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 20/156 reads (13%) | catalogued as rs1233844346, COSV66131979; called by muse, mutect2, varscan2
- DNAJC18 | c.676T>C p.Y226H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV57416525; called by muse, mutect2, varscan2
- DNAJC25 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57957505; called by muse, mutect2, varscan2
- DNASE1L1 | c.312-1G>A p.X104_splice | Splice Site (SNP) | VAF 10/38 reads (26%) | catalogued as COSV50010865; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOK4 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs146675149; called by muse, mutect2, varscan2
- DPH2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV52544527; called by mutect2, varscan2
- DRD5 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58576727; called by mutect2, varscan2
- DSE | c.532C>A p.L178I | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV59061693, COSV59067196; called by muse, mutect2, varscan2
- DST | c.3280C>A p.L1094M (on ENST00000361203 / NM_001374722.1; = p.L768M on NM_001723.6) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as rs756379041, COSV55031525; called by muse, mutect2, varscan2
- DTX1 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs935256741, COSV55657868; called by muse, mutect2
- DYRK2 | c.571C>T p.R191C (on ENST00000344096 / NM_006482.3; = p.R118C on NM_003583.4) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs893457223, COSV59847081; called by muse, mutect2, varscan2
- DYRK2 | c.1351C>T p.R451* (on ENST00000344096 / NM_006482.3; = p.R378* on NM_003583.4) | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV59847089; called by muse, mutect2, varscan2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 14/117 reads (12%) | catalogued as rs768937539; called by mutect2, pindel, varscan2
- EDF1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs139723037; called by muse, mutect2, varscan2
- EEF1G | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as COSV57748009; called by muse, varscan2
- EFNA2 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs774179869, COSV53066006; called by mutect2, varscan2
- EHBP1L1 | c.575A>G p.D192G | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58574379; called by muse, mutect2, varscan2
- EIF2AK4 | c.821G>T p.S274I | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV55472330; called by mutect2, varscan2
- EIF2B5 | c.1189G>A p.V397M (on ENST00000647909; = p.V389M on NM_003907.3) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56605683; called by muse, mutect2, varscan2
- EIF3B | c.2234A>G p.E745G | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV62804332; called by muse, mutect2, varscan2
- ENAM | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV68536686; called by muse, mutect2, varscan2
- ENAM | c.2817G>T p.R939S | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.343); catalogued as COSV68536694; called by muse, mutect2, varscan2
- ENTPD1 | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64603496; called by muse, mutect2, varscan2
- ENTPD5 | c.365del p.K122Rfs*6 | Frame Shift Del (DEL) | VAF 43/256 reads (17%) | catalogued as COSV58220608; called by mutect2, pindel, varscan2
- EP300 | c.1528+2T>C p.X510_splice | Splice Site (SNP) | VAF 8/80 reads (10%) | catalogued as COSV54340762; called by muse, mutect2, varscan2
- EPB41L2 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as COSV100441167; called by muse, mutect2, varscan2
- EPB41L4B | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746270390, COSV65798195; called by muse, mutect2, varscan2
- EPHA1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs200235266, COSV51974273; called by mutect2, varscan2
- EPHA3 | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60719363; called by muse, mutect2, varscan2
- EPHB2 | c.1201C>A p.H401N | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV65864940; called by muse, mutect2, varscan2
- EPHB4 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs998369671, COSV62269975; called by muse, mutect2, varscan2
- ERBB3 | c.3649C>A p.L1217I | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV57259676; called by muse, mutect2, varscan2
- ERBB4 | c.3449A>G p.Y1150C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1187421880, COSV61461311; called by muse, mutect2, varscan2
- ERC1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV61697976; called by muse, mutect2, varscan2
- ERICH3 | c.819G>A p.K273= | Splice Region (SNP) | VAF 6/73 reads (8%) | catalogued as COSV100443743, COSV58614119; called by muse, mutect2
- ERICH6 | c.542A>G p.K181R | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV55802288; called by muse, mutect2, varscan2
- ERV3-1 | c.1214T>G p.L405R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV99275917, COSV99275962, COSV99276117; called by muse, mutect2, varscan2
- ESYT1 | c.2443G>A p.G815S | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV57275362; called by muse, mutect2, varscan2
- EVC2 | c.3639G>T p.W1213C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.785); catalogued as COSV100187038, COSV60399299; called by muse, mutect2, varscan2
- EXD1 | c.317_319del p.E106del | In Frame Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs772638562; called by mutect2, pindel, varscan2
- EXT1 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65474319; called by muse, mutect2
- F5 | c.5192A>G p.Y1731C | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63126478; called by muse, mutect2, varscan2
- FAM111A | c.1075T>C p.Y359H | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV64655692; called by muse, mutect2, varscan2
- FAT1 | c.10822G>T p.G3608W | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71675372; called by muse, mutect2, varscan2
- FAT2 | c.6089G>A p.R2030Q | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs145039507; called by muse, mutect2, varscan2
- FAT2 | c.3152T>C p.V1051A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99943761; called by muse, mutect2
- FAT3 | c.3629G>T p.R1210M | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53153658, COSV99968948; called by muse, mutect2, varscan2
- FAT4 | c.5533G>A p.V1845M | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as rs1179341769, COSV58691310, COSV58700791; called by muse, mutect2, varscan2
- FAT4 | c.13964G>T p.R4655M | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58671839; called by muse, mutect2, varscan2
- FBP2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376034537; called by mutect2, varscan2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs772635228; called by mutect2, varscan2
- FCER2 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs200648991, COSV60916660; called by muse, mutect2
- FCRL1 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1377744519, COSV63826586; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | catalogued as rs748969702; called by mutect2, varscan2
- FGFR2 | c.1005G>T p.E335D | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.297); catalogued as COSV60655231; called by muse, mutect2, varscan2
- FGL2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); catalogued as rs1459657752, COSV50381411; called by muse, mutect2
- FHDC1 | c.3098C>T p.P1033L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767132760, COSV52602015; called by muse, mutect2, varscan2
- FKBP10 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.576); catalogued as rs781821453, COSV58638294; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FKBP3 | c.164A>C p.N55T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV53533336; called by muse, mutect2
- FKBP5 | c.847A>G p.K283E | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV61883180; called by muse, mutect2, varscan2
- FLG | c.5026A>G p.S1676G | Missense Mutation (SNP) | VAF 70/506 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV64236903, COSV64245756; called by muse, mutect2, varscan2
- FMNL1 | c.2819T>C p.M940T | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV58958329; called by muse, mutect2, varscan2
- FMNL2 | c.1114C>A p.L372M | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56501054; called by muse, mutect2, varscan2
- FPR1 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as COSV59053157, COSV59054057; called by muse, mutect2, varscan2
- FRYL | c.4174C>T p.L1392F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51956502; called by muse, mutect2, varscan2
- FUT11 | c.1331A>G p.D444G | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV59543984; called by muse, mutect2, varscan2
- FZD10 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs1392335994, COSV57473019; called by mutect2, varscan2
- G3BP2 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV62976431; called by muse, mutect2, varscan2
- GABRA3 | c.683A>C p.N228T | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.174); catalogued as COSV64803087; called by muse, mutect2, varscan2
- GABRG3 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1471042419, COSV61514312, COSV61529275; called by mutect2, varscan2
- GALNT13 | c.1282T>C p.Y428H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1452597025, COSV67232379; called by muse, mutect2, varscan2
- GAST | c.118A>G p.R40G | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV61475768; called by muse, mutect2, varscan2
- GBF1 | c.1297C>T p.H433Y (on ENST00000369983 / NM_001377137.1; = p.H432Y on NM_004193.3) | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV64147607; called by muse, mutect2, varscan2
- GCAT | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50649837; called by muse, mutect2, varscan2
- GET3 | c.401A>C p.E134A | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV62002830; called by muse, varscan2
- GGCX | c.899_901del p.S300del | In Frame Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs751262487; called by mutect2, pindel, varscan2
- GGTLC1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as rs1467760252, COSV53849467; called by muse, mutect2, varscan2
- GNE | c.1370T>C p.M457T (on ENST00000396594 / NM_001128227.3; = p.M426T on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.023); catalogued as rs774260686, COSV64952625; called by mutect2, varscan2
- GPBP1 | c.1054A>G p.I352V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV53313702; called by muse, varscan2
- GPC5 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as rs771309970, COSV100994380, COSV65617949; called by muse, mutect2, varscan2
- GPI | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV62894588; called by muse, mutect2, varscan2
- GPLD1 | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as COSV57759831; called by muse, mutect2, varscan2
- GPR19 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs764429834, COSV100196964; called by muse, mutect2, varscan2
- GPR26 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs953549609, COSV52935596; called by muse, mutect2
- GPRASP1 | c.3070G>A p.A1024T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV64356182; called by muse, mutect2, varscan2
- GRAMD1B | c.258G>A p.V86= | Splice Region (SNP) | VAF 14/79 reads (18%) | catalogued as COSV59208777; called by muse, mutect2, varscan2
- GRAMD2A | c.691T>C p.S231P | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs971575590, COSV59034682; called by muse, mutect2, varscan2
- GRM1 | c.1567G>C p.V523L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99268070; called by muse, mutect2, varscan2
- GSE1 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1331122391; called by muse, varscan2
- GTF3C4 | c.2174G>T p.R725I | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV64645851; called by muse, mutect2, varscan2
- GTPBP3 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs752605508, COSV50192215; called by muse, mutect2, varscan2
- GUF1 | c.1871G>A p.C624Y | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs913197565, COSV54947782; called by muse, mutect2, varscan2
- HCK | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52945814, COSV99393871; called by muse, mutect2
- HCRTR1 | c.1141G>T p.G381C | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV101035978; called by muse, mutect2, varscan2
- HDX | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868328516, COSV52976258, COSV52981132; called by muse, mutect2
- HEATR1 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs1452348478, COSV63982466; called by muse, mutect2, varscan2
- HECTD1 | c.6121del p.I2041Lfs*27 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as rs758518381; called by mutect2, pindel, varscan2
- HECTD3 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs774871050, COSV55801297; called by mutect2, varscan2
- HECTD4 | c.13100dup p.D4368Rfs*44 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | catalogued as rs746492036; called by mutect2, varscan2
- HECTD4 | c.7547A>G p.Y2516C | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66396918; called by muse, mutect2, varscan2
- HERC2 | c.9292A>G p.T3098A | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV55341438, COSV55353805; called by muse, mutect2, varscan2
- HLA-DMA | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs779711764, COSV66385643; called by muse, mutect2, varscan2
- HLA-DOA | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs552404381, COSV57715228; called by muse, mutect2, varscan2
- HNRNPH3 | c.166A>C p.S56R | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.679); catalogued as COSV56262974; called by muse, mutect2, varscan2
- HNRNPM | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1450635900, COSV55312788; called by muse, mutect2, varscan2
- HOXA3 | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs1562709790, COSV57828175; called by muse, mutect2, varscan2
- HOXC6 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV54537826; called by muse, mutect2, varscan2
- HP1BP3 | c.780G>T p.E260D | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.699); catalogued as COSV56562231; called by muse, mutect2, varscan2
- HSDL2 | c.149T>G p.L50R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52716478; called by muse, mutect2, varscan2
- HSPH1 | c.1453A>G p.N485D | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.788); catalogued as COSV60712869; called by muse, mutect2, varscan2
- HTT | c.7441G>A p.V2481M | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1443600938, COSV61866672; called by muse, mutect2, varscan2
- IAPP | c.259T>A p.L87M | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV53713321, COSV53714406; called by muse, mutect2, varscan2
- IDH3G | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1557069512, COSV99473333; called by muse, varscan2
- IFIT1 | c.1007del p.K336Sfs*9 | Frame Shift Del (DEL) | VAF 8/87 reads (9%) | catalogued as rs1202143274; called by mutect2, pindel
- IFNGR2 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs763384272, COSV51638539; called by muse, mutect2, varscan2
- IGSF1 | c.3535A>G p.I1179V | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.881); catalogued as COSV63839192; called by muse, mutect2, varscan2
- IL10RA | c.456del p.A153Qfs*33 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs1245259808; called by mutect2, pindel, varscan2
- IL1RAP | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50766938; called by muse, mutect2
- IL21R | c.1174T>G p.C392G | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100560367; called by muse, mutect2, varscan2
- INO80 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs202070069, COSV62741065; called by muse, mutect2, varscan2
- ISL1 | c.763A>G p.T255A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV57935018; called by muse, mutect2, varscan2
- ISM1 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); catalogued as COSV52606852; called by muse, mutect2, varscan2
- ITGA3 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772057144, COSV50327955; called by muse, mutect2, varscan2
- ITGB1 | c.1132C>A p.L378I | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56478983; called by muse, mutect2
- ITPR2 | c.5991G>T p.Q1997H | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67274002; called by muse, mutect2, varscan2
- JCAD | c.2050C>T p.H684Y | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as COSV64760003; called by muse, mutect2, varscan2
- JUP | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs369121094, COSV60279193; called by muse, mutect2, varscan2
- KBTBD6 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 24/143 reads (17%) | catalogued as rs370605552, COSV65271010; called by muse, mutect2, varscan2
- KBTBD8 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV55130561; called by muse, mutect2, varscan2
- KCNB2 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs373737384, COSV73050759; called by muse, mutect2, varscan2
- KCNH1 | c.2789G>A p.R930K (on ENST00000271751 / NM_172362.3; = p.R903K on NM_002238.4) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55094999; called by muse, mutect2, varscan2
- KCNH3 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs757600141, COSV57792132; called by muse, mutect2, varscan2
- KCNH5 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs1461051682, COSV59770436; called by muse, mutect2, varscan2
- KCNH8 | c.1618A>G p.M540V | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs751850908, COSV60472153; called by muse, varscan2
- KCNJ11 | c.674G>A p.S225N | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV60595191; called by muse, mutect2
- KCNQ3 | c.1751A>C p.K584T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.875); catalogued as COSV66477868; called by muse, mutect2, varscan2
- KCNS2 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as rs201873843, COSV54637904; called by muse, mutect2, varscan2
- KCNT2 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 22/155 reads (14%) | catalogued as COSV54098601, COSV99657059; called by muse, mutect2, varscan2
- KDR | c.3064C>T p.R1022* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV55759731; called by muse, mutect2, varscan2
- KHDC4 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64165457; called by muse, mutect2
- KIF13A | c.1578G>A p.W526* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV52460867; called by muse, mutect2, varscan2
- KIF6 | c.611del p.L204* | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | catalogued as rs777890702; called by pindel, varscan2
- KIR2DL4 | c.1018G>A p.A340T (on ENST00000396284; = p.A266T on NM_001080770.2) | Missense Mutation (SNP) | VAF 53/412 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.209); catalogued as rs763530813, COSV58495097; called by muse, mutect2, varscan2
- KIRREL1 | c.1292A>C p.N431T | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV63290080; called by muse, mutect2
- KLHL4 | c.1930G>T p.D644Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100909063, COSV64146097; called by muse, mutect2, varscan2
- KLHL8 | c.892A>G p.S298G | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV56748921; called by muse, mutect2, varscan2
- KLK4 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV60676597; called by muse, mutect2, varscan2
- KMT2C | c.10138C>T p.P3380S | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); catalogued as COSV51479897; called by muse, mutect2, varscan2
- KMT2D | c.16429T>G p.C5477G | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56470804; called by muse, mutect2, varscan2
- KMT2E | c.5228C>A p.P1743H | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV99996720; called by muse, mutect2, varscan2
- KNDC1 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs776648690, COSV58842260; called by muse, mutect2, varscan2
- KNOP1 | c.467del p.K156Rfs*57 | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | catalogued as rs960845807, COSV54929560; called by mutect2, pindel, varscan2
- KPNB1 | c.378G>A p.W126* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV51599352; called by mutect2, varscan2
- KRTAP19-1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs199797669, COSV66860928, COSV66861078; called by muse, mutect2, varscan2
- LAMA5 | c.8587G>A p.A2863T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV53367672; called by muse, mutect2, varscan2
- LAMB1 | c.3497C>T p.T1166M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs771248391, COSV55962713; called by mutect2, varscan2
- LBR | c.1745A>G p.H582R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55290785; called by muse, mutect2, varscan2
- LEXM | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542343089, COSV64023671; called by mutect2, varscan2
- LIG3 | c.596A>G p.Q199R | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV52009808; called by muse, mutect2, varscan2
- LILRB5 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752826486, COSV60259986; called by muse, mutect2, varscan2
- LIMD1 | c.1121G>A p.C374Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.365); catalogued as rs755410946, COSV56269164; called by muse, mutect2, varscan2
- LIPI | c.375A>C p.E125D | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as COSV60714686; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | catalogued as rs780042765; called by mutect2, varscan2
- LMO2 | c.305G>A p.R102H (on ENST00000395833 / NM_001142315.2; = p.R171H on NM_005574.4) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1401579360, COSV57645438; called by muse, mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | catalogued as rs748712732; called by mutect2, varscan2
- LPAR3 | c.139del p.S47Lfs*9 | Frame Shift Del (DEL) | VAF 38/266 reads (14%) | catalogued as rs762083435; called by mutect2, varscan2
- LPCAT4 | c.801+1G>A p.X267_splice | Splice Site (SNP) | VAF 9/60 reads (15%) | catalogued as COSV59217826; called by muse, mutect2, varscan2
- LPIN3 | c.2084T>C p.M695T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60037967; called by muse, varscan2
- LPP | c.542A>G p.K181R | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.134); catalogued as COSV57106867; called by muse, mutect2, varscan2
- LRP1B | c.10756A>C p.S3586R | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV67242427; called by muse, mutect2, varscan2
- LRP1B | c.8162C>A p.S2721Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.913); catalogued as COSV67207408; called by muse, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 23/125 reads (18%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC31 | c.1624del p.R542Efs*37 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | catalogued as rs748577734; called by mutect2, pindel, varscan2
- LRRC8A | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.137); catalogued as rs749079625, COSV52188258; called by muse, mutect2, varscan2
- LRRK2 | c.4915del p.R1639Gfs*15 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | catalogued as rs756089224; called by mutect2, varscan2
- LRTM1 | c.815A>T p.E272V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV55566066; called by muse, mutect2, varscan2
- LTA4H | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as COSV57383736; called by muse, mutect2, varscan2
- LTN1 | c.2855G>A p.S952N | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1373830884, COSV63734768; called by muse, mutect2
- MAGEC1 | c.2197G>T p.G733W | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53578402, COSV53579831; called by muse, varscan2
- MAMDC2 | c.1834T>G p.L612V | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.645); catalogued as COSV65859787; called by muse, mutect2, varscan2
- MAML2 | c.3308G>T p.S1103I | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV73264360; called by muse, mutect2, varscan2
- MAP7D1 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs879704861, COSV60217443; called by muse, mutect2, varscan2
- MAPK4 | c.446A>G p.D149G | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68543232; called by muse, varscan2
- MARF1 | c.3676G>A p.V1226I | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs929937817, COSV60025931; called by muse, mutect2, varscan2
- MARS1 | c.1859A>G p.Y620C | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs777332933, COSV56257538; called by muse, mutect2, varscan2
- MARVELD3 | c.669_670insT p.G224Wfs*25 | Frame Shift Ins (INS) | VAF 14/121 reads (12%) | catalogued as COSV99194855; called by mutect2, pindel, varscan2
- MBD3L1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV59776118, COSV59776282; called by muse, mutect2, varscan2
- MBD5 | c.3865C>T p.H1289Y | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV68698483; called by muse, mutect2, varscan2
- MC1R | c.838T>C p.F280L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV59626455; called by muse, mutect2, varscan2
- MCPH1 | c.1982A>G p.N661S | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV60917667; called by muse, mutect2, varscan2
- MDN1 | c.1401T>A p.Y467* | Nonsense Mutation (SNP) | VAF 39/266 reads (15%) | catalogued as COSV65527251; called by muse, mutect2, varscan2
- MEAK7 | c.558G>A p.W186* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV59145020; called by muse, mutect2, varscan2
- MED16 | c.1775T>C p.I592T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54130171; called by muse, mutect2, varscan2
- MED24 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as rs773751927, COSV62419348; called by mutect2, varscan2
- MFAP3L | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as rs1356046713, COSV64372733; called by muse, mutect2, varscan2
- MFN2 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 50/363 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV52424581; called by muse, mutect2, varscan2
- MGME1 | c.524A>G p.Q175R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV66624575; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 24/156 reads (15%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MMP15 | c.830T>C p.M277T | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54680929; called by muse, mutect2, varscan2
- MMP28 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs751685683; called by muse, mutect2, varscan2
- MN1 | c.3091G>A p.G1031R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as rs758293540, COSV56559601; called by muse, mutect2, varscan2
- MOB1A | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766736617, COSV68517818; called by muse, mutect2, varscan2
- MPHOSPH8 | c.947G>A p.S316N | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV64056957; called by muse, mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 30/164 reads (18%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRNIP | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs758236790, COSV52974593; called by muse, mutect2, varscan2
- MROH1 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); catalogued as rs1040586221; called by muse, mutect2, varscan2
- MRTFB | c.1834C>T p.R612W | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs763838057, COSV57960214; called by mutect2, varscan2
- MS4A4A | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs767663842, COSV59701569, COSV59702746; called by muse, mutect2, varscan2
- MTMR3 | c.3275G>A p.R1092H | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs756880491, COSV60307363; called by muse, mutect2, varscan2
- MTTP | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1368249156, COSV55508681; called by muse, mutect2, varscan2
- MUC16 | c.26161T>G p.S8721A | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV67482001; called by muse, mutect2, varscan2
- MYC | c.847_849del p.S283del (on ENST00000377970; = p.S298del on NM_002467.6) | In Frame Del (DEL) | VAF 5/50 reads (10%) | catalogued as rs1203089442; called by mutect2, pindel, varscan2
- MYH15 | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56316243; called by muse, mutect2, varscan2
- MYO18A | c.4537A>G p.T1513A | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.181); catalogued as COSV62871199; called by muse, mutect2, varscan2
- MYO5B | c.1543A>G p.K515E | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV53226630; called by muse, mutect2
- NAALADL2 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as COSV70795214; called by muse, mutect2, varscan2
- NAT8 | c.585G>C p.K195N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV55542883; called by muse, mutect2, varscan2
- NBN | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as rs1060504930, COSV55375607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAN | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs774053112, COSV53048184; called by muse, mutect2, varscan2
- NCKAP1L | c.1582G>A p.V528I | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs771766104, COSV53203245; called by muse, mutect2, varscan2
- NCKAP1L | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as rs991425204, COSV53210503; called by muse, mutect2, varscan2
- NECTIN4 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as COSV63513573; called by mutect2, varscan2
- NF1 | c.7439A>G p.H2480R (on ENST00000358273 / NM_001042492.3; = p.H2459R on NM_000267.3) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.015); catalogued as rs371151718, CM143476; ClinVar: uncertain significance; called by mutect2, varscan2
- NFATC2 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65359328; called by muse, mutect2, varscan2
- NHLRC1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs371072212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHLRC4 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV50318194; called by muse, mutect2, varscan2
- NID2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs147980330, COSV53496430; called by muse, mutect2, varscan2
- NLGN4Y | c.2365A>G p.M789V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV59298757; called by muse, mutect2, varscan2
- NLRC3 | c.3136G>A p.G1046R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368331294; called by muse, mutect2, varscan2
- NLRP2 | c.396A>C p.Q132H | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV54758603; called by muse, mutect2, varscan2
- NLRP9 | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as rs1483303774, COSV60466295; called by muse, mutect2, varscan2
- NOLC1 | c.1819A>G p.T607A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV64180869; called by muse, mutect2, varscan2
- NOS1 | c.2814G>T p.K938N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.696); catalogued as COSV57618239; called by muse, mutect2, varscan2
- NOVA1 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57483915; called by muse, mutect2, varscan2
- NPR1 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs753081607, COSV64117677; called by mutect2, varscan2
- NR2F2 | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1227439742, COSV101241131; called by muse, mutect2, varscan2
- NR3C2 | c.2870C>T p.P957L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60996908, COSV60999635; called by muse, mutect2, varscan2
- NRG2 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.092); catalogued as rs770568558, COSV56830352; called by mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as rs776154715; called by mutect2, varscan2
- NRP1 | c.2489C>T p.T830M | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.752); catalogued as rs750320738, COSV55160209; called by muse, mutect2, varscan2
- NSD3 | c.3526G>A p.G1176S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57672577; called by muse, mutect2, varscan2
- NSDHL | c.945T>A p.S315R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV64744839; called by muse, mutect2
- NSUN6 | c.1377del p.F459Lfs*6 | Frame Shift Del (DEL) | VAF 18/156 reads (12%) | catalogued as rs768858112, COSV56613929; called by mutect2, pindel, varscan2
- NT5C1B | c.1073C>T p.A358V (on ENST00000359846 / NM_001199086.2; = p.A298V on NM_033253.4) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV58397966; called by muse, mutect2, varscan2
- NT5DC2 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs200773348, COSV58740933; called by mutect2, varscan2
- NTRK3 | c.830A>G p.D277G | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.948); catalogued as COSV58135635; called by muse, mutect2
- NUAK1 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54606546; called by muse, mutect2, varscan2
- NUDT8 | c.382A>C p.S128R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as COSV100039867; called by muse, mutect2, varscan2
- NUFIP1 | c.526del p.C176Vfs*27 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | catalogued as rs1566064574; called by mutect2, pindel, varscan2
- NUP205 | c.3039dup p.P1014Tfs*48 | Frame Shift Ins (INS) | VAF 24/169 reads (14%) | catalogued as rs1459298648; called by mutect2, pindel, varscan2
- NUTM1 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV59218186; called by muse, mutect2, varscan2
- NYAP1 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.582); catalogued as COSV55720989; called by muse, mutect2
- OBI1 | c.1839del p.L614Sfs*9 | Frame Shift Del (DEL) | VAF 16/125 reads (13%) | catalogued as rs1320199922; called by mutect2, pindel, varscan2
- OCRL | c.2639C>A p.T880N | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV63981534; called by muse, mutect2, varscan2
- OGA | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV63382684; called by muse, mutect2, varscan2
- OR10K1 | c.227T>G p.V76G | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV56873336; called by muse, mutect2, varscan2
- OR10W1 | c.500A>G p.H167R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs755673017, COSV67720735; called by mutect2, varscan2
- OR10Z1 | c.611T>A p.L204H | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63524482; called by muse, mutect2, varscan2
- OR1K1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs748623617, COSV52956973; called by mutect2, varscan2
- OR1Q1 | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); catalogued as COSV52918717; called by muse, mutect2, varscan2
- OR4C12 | c.163T>C p.S55P | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as COSV58859956; called by muse, mutect2, varscan2
- OR4C46 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs1252951997, COSV60220693; called by muse, mutect2, varscan2
- OR4D9 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs749112385, COSV61435135; called by muse, mutect2, varscan2
- OR4Q3 | c.953C>G p.P318R | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.125); catalogued as COSV59177540, COSV59179709; called by muse, varscan2
- OR4S1 | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60679659; called by muse, mutect2, varscan2
- OR51B5 | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 16/123 reads (13%) | catalogued as COSV56175544; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs755413956; called by mutect2, varscan2
- OR5H1 | c.921del p.K307Nfs*? | Frame Shift Del (DEL) | VAF 9/85 reads (11%) | catalogued as rs750155763; called by mutect2, pindel, varscan2
- OR6C70 | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV59245210; called by muse, mutect2, varscan2
- OR6M1 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs779800001, COSV58434372; called by mutect2, varscan2
- ORAI2 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs149386719; called by muse, mutect2, varscan2
- PAFAH2 | c.677A>G p.D226G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV65339896; called by muse, mutect2, varscan2
- PAK2 | c.1391A>G p.Q464R | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV59083904; called by muse, mutect2, varscan2
- PARP11 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748949914, COSV57396666; called by muse, mutect2, varscan2
- PARP4 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772783590, COSV67961386; called by mutect2, varscan2
- PCDH11X | c.1252C>A p.L418M | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV53491939; called by muse, mutect2, varscan2
- PCDHA1 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as COSV65372694; called by muse, mutect2, varscan2
- PCDHA12 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.913); catalogued as COSV56532425; called by muse, mutect2, varscan2
- PCDHA8 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.163); catalogued as COSV65336233, COSV65336978; called by muse, mutect2, varscan2
- PCDHB2 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV52035795; called by muse, varscan2
- PCDHB2 | c.2117C>T p.S706L | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as rs782702170, COSV99166039; called by muse, mutect2, varscan2
- PCDHB8 | c.967A>G p.R323G | Missense Mutation (SNP) | VAF 18/351 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.065); catalogued as COSV50799123; called by muse, mutect2
- PCDHGA1 | c.767C>A p.P256Q | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.752); catalogued as COSV65298412; called by muse, mutect2, varscan2
- PCDHGA6 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.071); catalogued as COSV54001795; called by muse, mutect2, varscan2
- PCDHGB6 | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.084); catalogued as COSV54001809; called by muse, mutect2
- PCDHGB7 | c.2360T>C p.L787P | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV54001817; called by muse, mutect2, varscan2
- PCLO | c.5527C>T p.R1843C | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934051413, COSV61648684; called by muse, mutect2, varscan2
- PCSK2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs767747613, COSV52728215; called by muse, mutect2, varscan2
- PCYT2 | c.488G>C p.S163T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV58712232; called by muse, mutect2, varscan2
- PDS5B | c.1180A>T p.R394* | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as rs750827034, COSV59724936; called by muse, mutect2, varscan2
- PELI2 | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1445871537, COSV50714172; called by muse, mutect2
- PER2 | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV54526274; called by muse, mutect2, varscan2
- PGAM2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.225); catalogued as rs1224215042, COSV51977299; called by mutect2, varscan2
- PGBD4 | c.1343A>G p.H448R | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs750383046, COSV56628670; called by muse, mutect2, varscan2
- PGM3 | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.605); catalogued as COSV52283721; called by muse, mutect2, varscan2
- PHTF1 | c.1637del p.F546Sfs*2 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | catalogued as rs750248180; called by mutect2, varscan2
- PIBF1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs376737770; called by muse, mutect2, varscan2
- PIFO | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 59/336 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63864084; called by muse, mutect2, varscan2
- PIGN | c.2588T>C p.I863T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as rs1343444045, COSV62951034; called by muse, mutect2, varscan2
- PKHD1L1 | c.7549A>G p.I2517V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65749333; called by muse, mutect2
- PKLR | c.644del p.G215Afs*12 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as CD090472; called by mutect2, pindel, varscan2
- PLA2G10 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV55494051; called by muse, mutect2
- PLAC8L1 | c.59T>C p.I20T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV61014267; called by muse, mutect2, varscan2
- PLIN4 | c.1381G>A p.G461S (on ENST00000301286; = p.G476S on NM_001367868.2) | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.959); catalogued as rs376264671, COSV56689736; called by mutect2, varscan2
- PLK3 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV59500700; called by mutect2, varscan2
- PLXNA4 | c.3967C>T p.R1323W | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747801776, COSV58104969; called by muse, mutect2, varscan2
- PNN | c.2086C>T p.R696* | Nonsense Mutation (SNP) | VAF 30/219 reads (14%) | catalogued as rs1390036894, COSV53767750; called by muse, mutect2, varscan2
- POGK | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV63312096; called by muse, mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLR1A | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55694457; called by muse, mutect2, varscan2
- POLR1G | c.653del p.N218Ifs*4 | Frame Shift Del (DEL) | VAF 22/132 reads (17%) | catalogued as rs753626854; called by mutect2, varscan2
- POMK | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs746166929, COSV58858040; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.667C>A p.R223S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.362); catalogued as rs771652086, COSV53454706, COSV53455798; called by muse, mutect2, varscan2
- PPFIBP1 | c.2587C>T p.R863* (on ENST00000318304 / NM_177444.3; = p.R857* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 11/112 reads (10%) | catalogued as rs373264878, COSV57297095; called by mutect2, varscan2
- PPIF | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs574888085, COSV56551487; called by muse, varscan2
- PPIF | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56551493; called by muse, mutect2, varscan2
- PPP1R10 | c.930del p.V311Yfs*79 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs746108087; called by mutect2, varscan2
- PPP1R12B | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100407875; called by muse, mutect2, varscan2
- PPP1R3F | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.984); catalogued as COSV50019534; called by muse, mutect2, varscan2
- PPP1R8 | c.757C>T p.R253C (on ENST00000311772 / NM_014110.5; = p.R29C on NM_002713.4) | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV52579568; called by muse, mutect2, varscan2
- PREX2 | c.4492T>C p.C1498R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); catalogued as COSV55791100; called by muse, mutect2, varscan2
- PRKDC | c.10577C>T p.P3526L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452690515, COSV58052865; called by muse, mutect2, varscan2
- PRKG1 | c.1824del p.K608Nfs*11 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | catalogued as COSV100907251; called by mutect2, pindel, varscan2
- PRKN | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.391); catalogued as COSV100627183; called by muse, mutect2, varscan2
- PROM2 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs775576750, COSV58299919; called by muse, mutect2, varscan2
- PRPF40B | c.53C>T p.P18L (on ENST00000380281; = p.P12L on NM_012272.3) | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.995); catalogued as rs533114278, COSV56060983; called by muse, mutect2, varscan2
- PRPF8 | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59266303; called by muse, mutect2, varscan2
- PRSS36 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV51638829; called by muse, mutect2, varscan2
- PRTG | c.3403G>A p.D1135N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs546454157, COSV66836984; called by muse, mutect2, varscan2
- PRUNE2 | c.3278G>A p.R1093Q | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as rs200283459; called by muse, mutect2, varscan2
- PSMC3 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100099412, COSV54082164; called by muse, mutect2
- PTGDR | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs199553417, COSV60093424; called by mutect2, varscan2
- PTPN3 | c.2422G>A p.A808T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs995426157, COSV52709135; called by muse, mutect2, varscan2
- PTPN9 | c.1069T>C p.Y357H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60725254; called by muse, mutect2, varscan2
- PTPRO | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55518504; called by muse, mutect2, varscan2
- PTPRT | c.3830A>T p.E1277V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100625202, COSV61959394, COSV61962998; called by muse, mutect2, varscan2
- PYY | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.435); catalogued as rs763327469, COSV63971479; called by mutect2, varscan2
- QARS1 | c.560A>G p.K187R | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV60275760; called by muse, mutect2, varscan2
- R3HDM1 | c.3035G>A p.G1012D | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51529898; called by muse, mutect2
- RAB1B | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV57583721; called by muse, mutect2, varscan2
- RALGAPA2 | c.4697G>A p.R1566H | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs778982377, COSV52505810; called by muse, mutect2, varscan2
- RANBP10 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as rs995519805, COSV58160102; called by muse, mutect2
- RAPGEF5 | c.1463del p.K488Rfs*2 (on ENST00000401957 / NM_001367602.2; = p.K791Rfs*2 on NM_012294.5) | Frame Shift Del (DEL) | VAF 12/95 reads (13%) | catalogued as rs1562708461; called by mutect2, pindel, varscan2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as rs770990761; called by mutect2, pindel, varscan2
- RASAL2 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs775161081, COSV62719454; called by muse, mutect2, varscan2
- RBBP6 | c.2740A>G p.T914A | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV60507562; called by muse, mutect2, varscan2
- RBBP8 | c.36C>A p.N12K | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.086); catalogued as COSV59095029; called by muse, mutect2, varscan2
- RBM25 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.198); catalogued as rs1218930370, COSV56199207; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM4B | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs759274499, COSV59497792; called by muse, mutect2, varscan2
- RBMX2 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1233273285, COSV59729544, COSV59729730; called by muse, mutect2, varscan2
- RBP3 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs782729460; called by muse, varscan2
- RIF1 | c.4297G>T p.D1433Y | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54611988, COSV54621589; called by muse, mutect2, varscan2
- RIPK4 | c.1595G>A p.R532Q (on ENST00000352483; = p.R484Q on NM_020639.3) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.271); catalogued as rs777150995, COSV60189588; called by mutect2, varscan2
- RIPOR3 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761811071, COSV50397130; called by mutect2, varscan2
- RMI1 | c.1098C>G p.C366W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.24); catalogued as rs1220718830, COSV57937285; called by muse, mutect2, varscan2
- RNF113B | c.794del p.N265Tfs*43 | Frame Shift Del (DEL) | VAF 21/123 reads (17%) | catalogued as COSV57434378; called by mutect2, pindel, varscan2
- RNF145 | c.260C>A p.A87D (on ENST00000424310 / NM_001199383.2; = p.A115D on NM_144726.2) | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV50869734; called by muse, mutect2, varscan2
- RNF180 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV56964145; called by muse, mutect2, varscan2
- RNF182 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs376459249; called by muse, mutect2, varscan2
- RNF213 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs373877122; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel
- RPGRIP1L | c.2304G>A p.S768= | Splice Region (SNP) | VAF 12/96 reads (13%) | catalogued as rs770503381, COSV50912779; ClinVar: uncertain significance; called by mutect2, varscan2
- RPL10A | c.481_483del p.K161del | In Frame Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs1356922511; called by pindel, varscan2
- RPS6KA2 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.253); catalogued as COSV55826632; called by muse, mutect2, varscan2
- RRP12 | c.1765T>G p.F589V | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59670177; called by muse, mutect2, varscan2
- RSRC1 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs371922284, COSV55828997; called by mutect2, varscan2
- RSRC2 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.785); catalogued as rs976826205, COSV59206396; called by muse, mutect2, varscan2
- RUNX1 | c.756G>A p.W252* (on ENST00000344691 / NM_001001890.3; = p.W279* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | catalogued as CM154593, COSV55868793; called by muse, mutect2, varscan2
- RUNX1T1 | c.1183C>T p.R395W (on ENST00000265814 / NM_001198628.1; = p.R368W on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1448417558, COSV56155622; called by muse, mutect2, varscan2
- RUNX2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as rs147009083, COSV61844130; called by muse, mutect2, varscan2
- RXFP4 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.102); catalogued as COSV58148570; called by muse, mutect2, varscan2
- RYR3 | c.12490C>A p.L4164I (on ENST00000389232; = p.L4165I on NM_001036.6) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.054); catalogued as COSV66803156; called by muse, mutect2, varscan2
- SACS | c.11353del p.R3785Gfs*13 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | catalogued as COSV101207826; called by mutect2, pindel, varscan2
- SAGE1 | c.638del p.N213Mfs*11 | Frame Shift Del (DEL) | VAF 30/148 reads (20%) | catalogued as COSV100187710; called by mutect2, varscan2
- SALL3 | c.3854G>A p.R1285H | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as rs778334113, COSV73306140; called by muse, mutect2, varscan2
- SAMD9L | c.4547del p.N1516Mfs*10 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | catalogued as COSV59083791; called by mutect2, varscan2
- SEC16B | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.826); catalogued as rs369043622; called by mutect2, varscan2
- SEC61G | c.197+2T>C p.X66_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV61856183; called by muse, mutect2
- SEL1L2 | c.30A>G p.I10M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV53155853; called by muse, mutect2, varscan2
- SELL | c.527G>A p.W176* (on ENST00000650983; = p.W163* on NM_000655.5) | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as COSV52553875; called by muse, mutect2, varscan2
- SEMA4A | c.2191A>G p.S731G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV61773552; called by muse, mutect2
- SEMA4D | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1377357248, COSV59399018; called by muse, mutect2, varscan2
- SEMA5A | c.3017T>C p.I1006T | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV101228595; called by muse, mutect2
- SERINC3 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as COSV54857886; called by muse, mutect2, varscan2
- SERPINA12 | c.446A>C p.K149T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100369773, COSV57945434; called by muse, mutect2, varscan2
- SERPINA3 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV67586813; called by muse, mutect2, varscan2
- SERPINA9 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV54077047; called by muse, mutect2, varscan2
- SERTAD2 | c.943T>G p.*315Eext*45 | Nonstop Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV57640938; called by muse, mutect2, varscan2
- SETD5 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV56715406; called by muse, mutect2, varscan2
- SETX | c.7954C>A p.H2652N | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV56391366; called by muse, mutect2, varscan2
- SF3B1 | c.3164G>T p.W1055L | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59222227; called by muse, mutect2, varscan2
- SFTPB | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV60893959; called by muse, mutect2, varscan2
- SH3BP2 | c.823del p.R275Efs*3 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as rs776466609, COSV62555238; called by mutect2, pindel, varscan2
- SH3TC2 | c.3080T>C p.I1027T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV60466278; called by muse, mutect2
- SH3TC2 | c.3046A>G p.T1016A | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV60466284, COSV60467731; called by muse, mutect2, varscan2
- SIDT1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201672512, COSV53500759; called by muse, mutect2, varscan2
- SIPA1L3 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs776969515; called by mutect2, varscan2
- SIX6 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1344962002, COSV59803126; called by muse, mutect2
- SLC12A1 | c.2628del p.D877Mfs*46 | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | catalogued as rs1419151341, COSV66797187; called by mutect2, pindel, varscan2
- SLC13A5 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99546072; called by mutect2, varscan2
- SLC17A2 | c.1215T>A p.Y405* (on ENST00000265425; = p.M356K on NM_005835.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV55354148; called by muse, mutect2, varscan2
- SLC22A6 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs764704425, COSV64560393; called by muse, mutect2, varscan2
- SLC25A34 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs139368754; called by mutect2, varscan2
- SLC27A6 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as rs768100853, COSV52485929; called by mutect2, varscan2
- SLC28A1 | c.1772A>G p.Y591C | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54483150; called by mutect2, varscan2
- SLC30A9 | c.631del p.I211Yfs*2 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as COSV100048624; called by mutect2, pindel, varscan2
- SLC39A12 | c.1146G>A p.M382I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV66201288; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC44A2 | c.109T>C p.C37R | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59838205; called by muse, mutect2, varscan2
- SLC4A8 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868263140, COSV60656599; called by muse, mutect2, varscan2
- SLC6A1 | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55117685; called by muse, mutect2
- SLC6A14 | c.1099dup p.S367Ffs*23 | Frame Shift Ins (INS) | VAF 17/80 reads (21%) | catalogued as rs782577137; called by pindel, varscan2
- SLC9A1 | c.352+2T>C p.X118_splice | Splice Site (SNP) | VAF 9/60 reads (15%) | catalogued as COSV99849904; called by muse, mutect2, varscan2
- SLC9C2 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | catalogued as COSV62947935; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2049A>T p.G683= (on ENST00000540229 / NM_001371097.1; = p.G622= on NM_001009562.4) | Splice Region (SNP) | VAF 6/60 reads (10%) | catalogued as COSV67447815; called by muse, mutect2
- SLCO1C1 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV56877187; called by muse, mutect2, varscan2
- SLF1 | c.2723C>T p.A908V | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV54372387; called by muse, mutect2, varscan2
- SLITRK2 | c.820A>G p.R274G | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.069); catalogued as COSV59427704; called by muse, mutect2, varscan2
- SLITRK6 | c.1647del p.H551Ifs*7 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs755387608; called by mutect2, varscan2
- SMTN | c.2603A>G p.E868G | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60781284; called by muse, mutect2
- SNAI1 | c.103T>A p.Y35N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV54864721; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as rs1278336874; called by mutect2, pindel, varscan2
- SOWAHB | c.2245A>C p.S749R | Missense Mutation (SNP) | VAF 45/391 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV57554987; called by muse, mutect2, varscan2
- SPACA3 | c.581+2T>C p.X194_splice | Splice Site (SNP) | VAF 18/119 reads (15%) | catalogued as COSV52192089; called by muse, mutect2, varscan2
- SPART | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100768909, COSV62087320; called by muse, mutect2, varscan2
- SPATA31D1 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.113); catalogued as rs778459117, COSV61199267; called by muse, mutect2, varscan2
- SPATC1 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV66299576; called by muse, mutect2
- SPINK14 | c.271T>C p.F91L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.297); catalogued as COSV63658993; called by muse, mutect2, varscan2
- SPINK5 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs539094987, COSV56253861; called by muse, mutect2, varscan2
- SPSB2 | c.392G>A p.W131* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as rs376241948; called by muse, mutect2, varscan2
- SPTA1 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV63757364; called by muse, mutect2, varscan2
- SRCAP | c.6536del p.K2179Rfs*128 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as COSV52675361; called by mutect2, varscan2
- SSBP2 | c.1029T>A p.N343K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as COSV57801857; called by muse, mutect2, varscan2
- ST3GAL4 | c.496C>T p.R166C (on ENST00000392669 / NM_001254758.1; = p.R162C on NM_006278.3) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565426493, COSV57106541; called by muse, mutect2, varscan2
- ST8SIA4 | c.693A>C p.K231N | Missense Mutation (SNP) | VAF 26/184 reads (14%) | PolyPhen benign (0.103); catalogued as COSV51514254; called by muse, mutect2, varscan2
- STAB2 | c.7651C>G p.L2551V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV66344054; called by mutect2, varscan2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | catalogued as rs746501298; called by mutect2, varscan2
- STEAP4 | c.199T>C p.Y67H | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV57330713; called by muse, mutect2, varscan2
- STIM2 | c.1460A>C p.D487A | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52842003; called by muse, mutect2
- STMN1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs763117641, COSV63481402; called by muse, mutect2, varscan2
- STN1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as rs183917764; called by mutect2, varscan2
- STX7 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs773669589, COSV63399122; called by muse, mutect2, varscan2
- SUGP2 | c.746A>T p.N249I | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV58262858; called by muse, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as rs747003550; called by mutect2, varscan2
- SUPT20H | c.396+2T>C p.X132_splice (on ENST00000350612 / NM_001014286.3; = p.X133_splice on NM_017569.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as COSV62248969; called by muse, mutect2, varscan2
- SV2C | c.1896T>A p.S632R | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59225913; called by muse, mutect2, varscan2
- SYNDIG1L | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV59048128; called by muse, mutect2, varscan2
- SYNE1 | c.7437A>C p.K2479N (on ENST00000367255 / NM_182961.4; = p.K2486N on NM_033071.3) | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV55057397; called by muse, mutect2, varscan2
- SYNE2 | c.8288C>T p.S2763L | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV59962577; called by muse, mutect2
- SYNJ2BP | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99832669; called by muse, mutect2, varscan2
- TAMM41 | c.806dup p.N269Kfs*14 | Frame Shift Ins (INS) | VAF 11/94 reads (12%) | catalogued as rs768826552; called by mutect2, pindel, varscan2
- TAMM41 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.039); catalogued as rs374882230; called by muse, mutect2, varscan2
- TAS1R2 | c.2404G>A p.A802T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV64746414; called by muse, mutect2, varscan2
- TAX1BP1 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55295623; called by muse, mutect2, varscan2
- TBATA | c.278-1G>A p.X93_splice | Splice Site (SNP) | VAF 13/66 reads (20%) | catalogued as COSV54720693; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D8 | c.3278T>C p.L1093P | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51822666; called by muse, mutect2, varscan2
- TBC1D9B | c.3283G>A p.A1095T (on ENST00000356834 / NM_198868.3; = p.A1078T on NM_015043.4) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs113335971; called by mutect2, varscan2
- TBX18 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201883996, COSV100858552; called by muse, mutect2, varscan2
- TBX2 | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV53600429; called by muse, mutect2, varscan2
- TBX3 | c.344A>G p.Q115R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as COSV57474206; called by muse, mutect2, varscan2
- TCP11L1 | c.637A>G p.R213G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV57516961; called by muse, mutect2, varscan2
- TCTE1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.04); catalogued as rs746423492, COSV65255618; called by muse, mutect2, varscan2
- TEP1 | c.1138T>C p.Y380H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52997160; called by muse, mutect2, varscan2
- TET2 | c.651del p.V218Wfs*32 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | catalogued as rs749148733, COSV54440058; called by mutect2, varscan2
- TFDP1 | c.49T>A p.F17I | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV64739530, COSV64741806; called by muse, mutect2, varscan2
- TIAM2 | c.5125G>A p.V1709I (on ENST00000529824; = p.V1680I on NM_012454.3) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs773674754, COSV51643284; called by mutect2, varscan2
- TIGD4 | c.533del p.N178Mfs*5 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs762008334; called by mutect2, pindel, varscan2
- TIMELESS | c.3556+2T>C p.X1186_splice | Splice Site (SNP) | VAF 26/137 reads (19%) | catalogued as COSV57513949; called by muse, mutect2, varscan2
- TIMELESS | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759412572, COSV57513963; called by muse, mutect2, varscan2
- TIMM50 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58680250; called by muse, mutect2, varscan2
- TLN1 | c.5368G>A p.A1790T | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs754790750, COSV59210297; called by muse, mutect2, varscan2
- TLN2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs532505276, COSV60893303; called by muse, mutect2, varscan2
- TLR3 | c.38dup p.L14Pfs*18 | Frame Shift Ins (INS) | VAF 13/89 reads (15%) | catalogued as rs757908313; called by mutect2, varscan2
- TMA16 | c.45del p.V16Sfs*25 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs570113265, COSV62187391; called by mutect2, varscan2
- TMEM198 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99525267; called by muse, mutect2, varscan2
- TMEM255B | c.969del p.Y324Tfs*9 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as COSV100944145; called by mutect2, pindel, varscan2
- TMPRSS6 | c.22del p.Q8Rfs*60 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | catalogued as rs759084210; called by mutect2, pindel, varscan2
- TMPRSS9 | c.2501C>T p.T834M (on ENST00000648592; = p.T800M on NM_182973.2) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs369734929, COSV53115072; called by mutect2, varscan2
- TMTC3 | c.1554del p.K518Nfs*11 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | catalogued as rs746894544; called by mutect2, pindel, varscan2
- TNFAIP3 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750716064, COSV52801157; called by muse, mutect2, varscan2
- TNFRSF9 | c.345del p.G116Vfs*33 | Frame Shift Del (DEL) | VAF 24/132 reads (18%) | catalogued as rs752649731; called by mutect2, varscan2
- TNR | c.3089G>C p.S1030T | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54904253; called by muse, mutect2, varscan2
- TOM1L2 | c.1289C>T p.A430V (on ENST00000379504 / NM_001350333.2; = p.A380V on NM_001033551.3) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1209314216, COSV58888088; called by muse, mutect2, varscan2
- TPP2 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65754124; called by muse, mutect2, varscan2
- TRAM1 | c.811A>T p.T271S | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as COSV51599675; called by muse, mutect2, varscan2
- TRAM1L1 | c.1033dup p.R345Kfs*13 | Frame Shift Ins (INS) | VAF 22/168 reads (13%) | catalogued as rs1237787070; called by mutect2, varscan2
- TRIM37 | c.2543C>T p.A848V | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs770505316, COSV51887229; ClinVar: uncertain significance; called by muse, mutect2
- TRIOBP | c.3506G>A p.R1169Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs780058028, COSV60381311; called by mutect2, varscan2
- TRMT9B | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs184909958, COSV71600038; called by muse, mutect2, varscan2
- TSPAN5 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59877894; called by muse, mutect2, varscan2
- TSR1 | c.193_195del p.K65del | In Frame Del (DEL) | VAF 12/90 reads (13%) | catalogued as rs1351262354; called by pindel, varscan2
- TSSK2 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99351094; called by muse, mutect2, varscan2
- TTC13 | c.1676T>C p.L559S | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.122); catalogued as COSV64169491; called by muse, mutect2, varscan2
- TTC21B | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs1263741987, COSV54633319; called by muse, mutect2, varscan2
- TTI1 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs141770247, COSV65060275; called by mutect2, varscan2
- TTI2 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV62453277; called by muse, mutect2, varscan2
- TTK | c.463T>A p.S155T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57885705; called by muse, mutect2, varscan2
- TTN | c.3476G>A p.R1159H (on ENST00000591111; = p.R1113H on NM_003319.4) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | PolyPhen probably damaging (0.938); catalogued as rs149883066, COSV59962444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUT4 | c.4753G>A p.A1585T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.104); catalogued as COSV57118000; called by muse, mutect2
- TXNDC11 | c.1432G>A p.G478R (on ENST00000356957 / NM_001303447.2; = p.G451R on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs752545906, COSV51599787; called by muse, mutect2, varscan2
- TYW1 | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.068); catalogued as COSV62754801; called by muse, mutect2, varscan2
- U2SURP | c.2598del p.K866Nfs*10 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as COSV67533295; called by mutect2, pindel, varscan2
- UBR4 | c.11593G>T p.G3865C | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64395879; called by muse, mutect2, varscan2
- UBR5 | c.5831T>C p.L1944S | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55295567; called by muse, mutect2, varscan2
- UGT8 | c.1378C>A p.L460I | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV60419826; called by muse, mutect2, varscan2
- UMODL1 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV68557127; called by muse, mutect2, varscan2
- UNC13D | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs538734085, COSV52886481; called by muse, mutect2, varscan2
- UPF2 | c.2168G>A p.R723K | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV62662613; called by muse, mutect2, varscan2
- UPF2 | c.565T>G p.L189V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as COSV62662617; called by muse, mutect2
- USE1 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV99812571; called by muse, varscan2
- USP21 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.028); catalogued as rs1272278343, COSV57090410; called by muse, mutect2, varscan2
- USP26 | c.1461dup p.G488Wfs*6 | Frame Shift Ins (INS) | VAF 22/92 reads (24%) | catalogued as rs761320003; called by mutect2, varscan2
- USP26 | c.1044del p.F348Lfs*7 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as CM077651, COSV63708747; called by mutect2, varscan2
- USP9X | c.2648G>C p.G883A | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61073200; called by muse, mutect2, varscan2
- UTP4 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58733957; called by muse, mutect2, varscan2
- UVSSA | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66230574; called by muse, mutect2, varscan2
- VGLL3 | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV67354002; called by muse, mutect2, varscan2
- VN1R2 | c.1108C>A p.R370S | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.281); catalogued as rs141012802, COSV59039240; called by muse, varscan2
- VPS13A | c.1357+2T>C p.X453_splice | Splice Site (SNP) | VAF 15/119 reads (13%) | catalogued as COSV62435377; called by muse, mutect2, varscan2
- VPS13D | c.6931G>A p.A2311T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs1176449930, COSV50664170; called by muse, mutect2, varscan2
- VPS50 | c.1310T>C p.L437S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58509907; called by muse, mutect2, varscan2
- VPS9D1 | c.1748G>A p.G583D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs1486069715, COSV66994707; called by muse, mutect2, varscan2
- VWA8 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369778717; called by mutect2, varscan2
- WDCP | c.1655A>G p.K552R | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.341); catalogued as COSV54593267; called by muse, mutect2, varscan2
- WDFY3 | c.7322A>G p.Y2441C | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV55710043; called by muse, mutect2, varscan2
- WDR19 | c.2743G>C p.V915L | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs183029614, COSV56468371; called by muse, mutect2, varscan2
- WDR25 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs367860354; called by muse, mutect2, varscan2
- WDR47 | c.1444A>G p.K482E (on ENST00000369962 / NM_001142551.2; = p.K483E on NM_014969.5) | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as COSV104415306, COSV63059128; called by muse, mutect2, varscan2
- WDR49 | c.1304T>G p.L435R (on ENST00000308378 / NM_001366158.1; = p.L776R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57714419; called by muse, mutect2
- WDR75 | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV59106528; called by muse, mutect2
- WDR93 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as COSV51533353; called by muse, mutect2, varscan2
- XKR6 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs766971738, COSV100440148, COSV58657755; called by mutect2, varscan2
- XPO4 | c.893G>A p.C298Y | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55011227; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 22/103 reads (21%) | catalogued as rs762052135; called by mutect2, varscan2
- XRCC1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752532258, COSV99486649; called by muse, mutect2, varscan2
- XRCC5 | c.851T>A p.L284Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.054); catalogued as COSV67537334; called by mutect2, varscan2
- XYLB | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs2234625, COSV52915042; called by muse, mutect2, varscan2
- ZAP70 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV53856215, COSV99385818, COSV99386116; called by muse, mutect2, varscan2
- ZBTB21 | c.2984A>G p.K995R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV60405256; called by muse, mutect2
- ZBTB38 | c.690A>C p.E230D | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1162112611, COSV58543514; called by muse, mutect2, varscan2
- ZBTB41 | c.1859A>G p.K620R | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV66359714; called by muse, mutect2, varscan2
- ZC3H14 | c.1790T>A p.L597H | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51772191; called by muse, mutect2, varscan2
- ZCCHC14 | c.1662C>A p.S554R (on ENST00000268616; = p.S691R on NM_015144.3) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.302); catalogued as rs200914568, COSV51889044; called by mutect2, varscan2
- ZDHHC15 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100973834, COSV64903033; called by muse, mutect2, varscan2
- ZFHX4 | c.1230dup p.L411Afs*3 | Frame Shift Ins (INS) | VAF 18/58 reads (31%) | catalogued as rs761578656; called by mutect2, varscan2
- ZFHX4 | c.7982G>A p.R2661K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV50725157, COSV51478022; called by muse, varscan2
- ZFP42 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as rs201496236, COSV58816371, COSV58818564; called by muse, mutect2, varscan2
- ZMAT1 | c.1063A>T p.R355* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV65657857, COSV65659585; called by muse, mutect2, varscan2
- ZMYM5 | c.1388del p.K463Rfs*11 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as rs1392316624; called by mutect2, pindel
- ZMYM6 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV58185065; called by muse, mutect2, varscan2
- ZNF148 | c.2200C>T p.R734C | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV62306658; called by muse, mutect2, varscan2
- ZNF165 | c.387A>C p.R129S | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV66102805; called by muse, mutect2, varscan2
- ZNF23 | c.535T>C p.C179R | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61841493; called by muse, mutect2, varscan2
- ZNF292 | c.1243C>G p.Q415E | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV60544227; called by muse, mutect2, varscan2
- ZNF3 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV52796337; called by muse, mutect2, varscan2
- ZNF34 | c.664del p.T222Qfs*15 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs751927309; called by mutect2, varscan2
- ZNF398 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV60066211; called by muse, mutect2, varscan2
- ZNF44 | c.580T>C p.C194R (on ENST00000356109 / NM_001164276.2; = p.C146R on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs780856263, COSV61135987; called by mutect2, varscan2
- ZNF454 | c.1546A>G p.R516G | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV60769571; called by muse, mutect2, varscan2
- ZNF512B | c.1360C>T p.R454* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as rs1413914978, COSV53875812, COSV53876221; called by muse, mutect2, varscan2
- ZNF514 | c.100T>G p.F34V | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV54635011; called by muse, mutect2, varscan2
- ZNF540 | c.843del p.F281Lfs*4 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | catalogued as rs757107073, COSV57110076; called by mutect2, pindel, varscan2
- ZNF574 | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as rs369467558; called by mutect2, varscan2
- ZNF608 | c.1393del p.A465Pfs*46 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | catalogued as rs764779166; called by mutect2, pindel, varscan2
- ZNF611 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV60542608; called by muse, mutect2, varscan2
- ZNF622 | c.140T>C p.F47S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58074871; called by muse, mutect2, varscan2
- ZNF626 | c.345del p.G116Dfs*3 | Frame Shift Del (DEL) | VAF 17/143 reads (12%) | catalogued as rs782441698; called by mutect2, pindel, varscan2
- ZNF638 | c.3912del p.G1305Vfs*22 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | catalogued as rs1196097264; called by mutect2, varscan2
- ZNF667 | c.1033C>A p.L345M | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV52637880; called by muse, mutect2, varscan2
- ZNF691 | c.775G>A p.E259K (on ENST00000372502; = p.E228K on NM_015911.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV65289568; called by muse, mutect2, varscan2
- ZNF780B | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.258); catalogued as COSV55466949; called by muse, mutect2, varscan2
- ZNF808 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV100708120; called by muse, mutect2
- ABR | c.205del p.D69Mfs*23 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by pindel, varscan2
- AC008397.2 | c.1062del p.Q355Rfs*6 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | called by mutect2, pindel, varscan2
- AHR | c.2190del p.T731Lfs*5 | Frame Shift Del (DEL) | VAF 20/125 reads (16%) | called by mutect2, pindel, varscan2
- AKAP11 | c.898del p.S300Rfs*30 | Frame Shift Del (DEL) | VAF 9/96 reads (9%) | called by mutect2, pindel
- ANKRD12 | c.2949del p.K983Nfs*4 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | called by mutect2, varscan2
- ARHGEF10 | c.914dup p.Q306Afs*5 (on ENST00000398564; = p.Q281Afs*5 on NM_014629.4) | Frame Shift Ins (INS) | VAF 12/123 reads (10%) | called by mutect2, pindel
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | called by mutect2, pindel, varscan2
- ATG4B | c.107del p.F36Sfs*46 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel
410 further variants in this file (133 protein-altering or splice-affecting, 258 silent, 19 other) are not listed here.
